Somatic mutation profile of tumor specimen C3L-02647-01 (aliquot CPT0193080007) from CPTAC case C3L-02647, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.1 years (25,244 days).
Specimen C3L-02647-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97637bca-0d21-4ee8-85cc-70d842e4a07b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02647-31 (Blood Derived Normal), aliquot CPT0193240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac2d0f35-a971-4484-97f9-9cae67f6df50

The open-access MAF lists 248 somatic variants for this specimen: 149 protein-altering or splice-affecting, 89 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 89, Nonsense Mutation 6, Intron 6, Splice Region 2, 5'UTR 1, 3'UTR 1, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACACA | c.4510C>T p.R1504C | Missense Mutation (SNP) | VAF 140/505 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs752673905; called by muse, mutect2, varscan2
- ADAMTS18 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs868333047, COSV51411009, COSV99273813; called by muse, mutect2
- ADCY8 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53917263, COSV53935546; called by muse, mutect2
- ALPK2 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 99/459 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs1465934483; called by muse, mutect2, varscan2
- AUTS2 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 54/823 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as rs1184884717, COSV61396619; called by muse, mutect2
- C9orf40 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65228629; called by muse, mutect2
- CD163L1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV58021540; called by muse, mutect2, varscan2
- CFAP54 | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 92/299 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201879966, COSV61571274, COSV61576136; called by muse, mutect2, varscan2
- CFH | c.3658G>A p.D1220N | Missense Mutation (SNP) | VAF 116/419 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV66407133; called by muse, mutect2, varscan2
- COL14A1 | c.4619G>A p.G1540D | Missense Mutation (SNP) | VAF 83/522 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.062); catalogued as rs1439888501; called by muse, mutect2, varscan2
- COL4A2 | c.2657C>T p.S886F | Missense Mutation (SNP) | VAF 183/498 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1037576655; called by muse, mutect2, varscan2
- CR1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as COSV100887298; called by muse, mutect2, varscan2
- CRHR2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 14/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59268627; called by muse, mutect2
- DMBT1 | c.5366C>T p.S1789F (on ENST00000338354 / NM_001377530.1; = p.S1032F on NM_004406.3) | Missense Mutation (SNP) | VAF 156/448 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57546599; called by muse, mutect2, varscan2
- DNAH11 | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs563280837, COSV60956774; ClinVar: uncertain significance; called by muse, mutect2
- DNAH14 | c.8053G>A p.E2685K (on ENST00000445597; = p.E3488K on NM_001367479.1) | Missense Mutation (SNP) | VAF 109/402 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs917132485, COSV59898014; called by muse, mutect2, varscan2
- DOLPP1 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.269); catalogued as rs750831844; called by muse, mutect2
- DSG4 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 87/398 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs758840509, COSV57397410; called by muse, mutect2, varscan2
- DUOX1 | c.2720C>T p.S907L | Missense Mutation (SNP) | VAF 176/533 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs139045084; called by muse, mutect2, varscan2
- EDAR | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 162/483 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51500538; called by muse, mutect2, varscan2
- F13A1 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 68/502 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs781240042, COSV53552778; called by muse, varscan2
- FAM126A | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 124/467 reads (27%) | catalogued as COSV69471779; called by muse, mutect2
- FGD5 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 202/630 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.107); catalogued as rs577170328; called by muse, mutect2, varscan2
- FPR1 | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 156/444 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs567895941; called by muse, mutect2, varscan2
- FRMD1 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 115/259 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.08); catalogued as rs765120490; called by muse, mutect2, varscan2
- GHSR | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 95/377 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs766092209; called by muse, mutect2, varscan2
- GOLGA6D | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 154/529 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1161262542; called by muse, mutect2, varscan2
- GPR148 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 146/496 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs772482512; called by muse, mutect2, varscan2
- IGLV9-49 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 104/381 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs112293276; called by muse, mutect2, varscan2
- KHSRP | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 103/451 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1355376332; called by muse, mutect2, varscan2
- KIAA1328 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 79/291 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1323553621; called by muse, mutect2, varscan2
- KIF26A | c.3820C>T p.Q1274* | Nonsense Mutation (SNP) | VAF 168/572 reads (29%) | catalogued as COSV100180740; called by muse, mutect2, varscan2
- KRT33B | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 139/539 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs149801180, COSV52441348; called by muse, mutect2, varscan2
- LILRA2 | c.33C>A p.L11= | Splice Region (SNP) | VAF 124/920 reads (13%) | catalogued as COSV99252747; called by muse, mutect2, varscan2
- LRP1B | c.9944C>T p.S3315F | Missense Mutation (SNP) | VAF 69/336 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101257792, COSV67255758; called by muse, mutect2, varscan2
- LRRC56 | c.1234dup p.W412Lfs*8 | Frame Shift Ins (INS) | VAF 37/337 reads (11%) | catalogued as COSV99530150; called by mutect2, pindel, varscan2
- MAGEB6 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 123/204 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV66872649; called by muse, mutect2, varscan2
- MTIF2 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs146855736; called by muse, mutect2, varscan2
- MUC2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 162/375 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs750381424; called by muse, mutect2, varscan2
- MXRA5 | c.5839G>A p.V1947M | Missense Mutation (SNP) | VAF 204/313 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV54248924; called by muse, mutect2, varscan2
- MYH4 | c.4690C>T p.R1564C | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs149046569, COSV55128124; called by muse, mutect2, varscan2
- NDN | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 143/434 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV59358650; called by muse, mutect2, varscan2
- NXPE4 | c.1114G>A p.D372N (on ENST00000375478 / NM_001077639.2; = p.D88N on NM_017678.3) | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as COSV100970341; called by muse, mutect2, varscan2
- OBSCN | c.18946G>A p.G6316S | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs776880255; called by muse, mutect2, varscan2
- OR2F1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 152/571 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471395131; called by muse, mutect2, varscan2
- OR2T3 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 128/1149 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV62082547; called by muse, mutect2, varscan2
- OR51B5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs267602946, COSV56176675; called by muse, mutect2, varscan2
- PCDH11Y | c.3044C>T p.S1015L (on ENST00000400457 / NM_032973.2; = p.S1004L on NM_032971.3) | Missense Mutation (SNP) | VAF 143/318 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53087644; called by muse, mutect2, varscan2
- PDGFRB | c.2096C>T p.T699I | Missense Mutation (SNP) | VAF 138/555 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1465893615; called by muse, mutect2, varscan2
- PEAK1 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.598); catalogued as rs1160892253; called by muse, mutect2, varscan2
- PPP4R3C | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1205988528; called by muse, mutect2
- PRAMEF20 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs202075096; called by muse, mutect2, varscan2
- PYGO1 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 115/367 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100114662; called by muse, mutect2, varscan2
- RGS13 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67346139; called by muse, mutect2, varscan2
- RIMS2 | c.3278C>T p.P1093L (on ENST00000666250 / NM_001348490.2; = p.P901L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/513 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99210639; called by muse, mutect2, varscan2
- RINL | c.1210C>T p.P404S (on ENST00000591812 / NM_001195833.2; = p.P290S on NM_198445.4) | Missense Mutation (SNP) | VAF 187/576 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs777872922; called by muse, mutect2, varscan2
- RNF41 | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 23/552 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs945181194; called by muse, mutect2
- SALL3 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 169/659 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV101610084; called by muse, mutect2, varscan2
- SLCO2B1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 237/562 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1009964902, COSV99215093; called by muse, mutect2, varscan2
- SPEM2 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 19/606 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV100424191; called by muse, mutect2
- SPIDR | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 143/545 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs762278735; called by muse, mutect2, varscan2
- SSPN | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 148/483 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs867658451, COSV54380732; called by muse, mutect2, varscan2
- STRC | c.5033G>A p.G1678E | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1339299254, COSV55853574; called by muse, mutect2, varscan2
- STYK1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554694983, COSV50012296; called by muse, mutect2, varscan2
- TDRD5 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867687242, COSV54242060; called by muse, mutect2, varscan2
- THPO | c.727G>A p.G243R (on ENST00000649095 / NM_001290003.1; = p.G103R on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 151/523 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs759092382, COSV52617508; called by muse, mutect2, varscan2
- TRIM49B | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 125/583 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.878); catalogued as COSV60322570; called by muse, mutect2, varscan2
- TRPM8 | c.2297C>T p.P766L | Missense Mutation (SNP) | VAF 116/508 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs778608904; called by mutect2, varscan2
- TTN | c.94421G>A p.G31474D (on ENST00000591111; = p.G24050D on NM_003319.4) | Missense Mutation (SNP) | VAF 114/390 reads (29%) | PolyPhen probably damaging (0.999); catalogued as rs879247634; ClinVar: uncertain significance; called by muse, varscan2
- VPS18 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 143/607 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs755373447; called by muse, mutect2, varscan2
- WAC | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs759496172, COSV61568766, COSV61569330; called by muse, mutect2, varscan2
- WSCD1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759368488; called by muse, mutect2, varscan2
- XPO7 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 81/535 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV104384366; called by muse, mutect2, varscan2
- ZIC4 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 102/421 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs972703553, COSV67172659; called by muse, mutect2, varscan2
- ZNF292 | c.6677C>T p.S2226L | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV60535205; called by muse, mutect2, varscan2
- ZNF292 | c.7385C>T p.S2462L | Missense Mutation (SNP) | VAF 177/489 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774250446; called by muse, mutect2, varscan2
- ZNF354B | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs867861557; called by muse, varscan2
- ZNF792 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 160/495 reads (32%) | catalogued as rs140967841, COSV68694374; called by muse, mutect2, varscan2
- AC011462.1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 100/545 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- APOC1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 133/504 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ATAD2 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 30/669 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.052); called by muse, mutect2
- CFAP44 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CLDN24 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 147/549 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL21A1 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 144/234 reads (62%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSH1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 138/540 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.7378G>A p.E2460K (on ENST00000297405 / NM_001363185.1; = p.E2356K on NM_052900.3) | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CSN2 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.164); called by muse, mutect2
- CUX1 | c.1277T>C p.L426S | Missense Mutation (SNP) | VAF 18/670 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2
- CYP4A11 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DST | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DUSP8 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 54/496 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTHD1 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 131/458 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- F11R | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- FAM126A | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 124/482 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- FOXN2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 170/527 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIK2 | c.2602T>A p.S868T | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HIVEP3 | c.3070T>C p.S1024P | Missense Mutation (SNP) | VAF 174/562 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV2-18 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 120/377 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- IQCM | c.39T>C p.C13= | Splice Region (SNP) | VAF 56/280 reads (20%) | called by muse, mutect2
- KLK8 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2
- KMT2C | c.13553A>G p.Y4518C | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KRTAP25-1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 133/480 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LAMC1 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 38/665 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- MGAM2 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); called by muse, mutect2
- MRM1 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 24/878 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.27); called by muse, mutect2
- MTHFR | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MXRA5 | c.5840T>A p.V1947E | Missense Mutation (SNP) | VAF 206/313 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MYO10 | c.5498T>C p.L1833P | Missense Mutation (SNP) | VAF 116/432 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP7 | c.1485G>A p.W495* | Nonsense Mutation (SNP) | VAF 240/786 reads (31%) | called by muse, mutect2, varscan2
- NSRP1 | c.364A>T p.M122L | Missense Mutation (SNP) | VAF 99/343 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- OR2T34 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- OR51V1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8H3 | c.291C>G p.C97W | Missense Mutation (SNP) | VAF 158/576 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OR9K2 | c.321G>A p.M107I (on ENST00000305377; = p.M85I on NM_001005243.1) | Missense Mutation (SNP) | VAF 93/480 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PADI6 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PCSK5 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- PLIN4 | c.3247G>A p.D1083N (on ENST00000301286; = p.D1098N on NM_001367868.2) | Missense Mutation (SNP) | VAF 143/626 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNMA6E | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 215/359 reads (60%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- POLR3E | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 195/427 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PPARD | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 102/621 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PRTG | c.835T>C p.F279L | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2
- RGS9 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RINL | c.1211C>T p.P404L (on ENST00000591812 / NM_001195833.2; = p.P290L on NM_198445.4) | Missense Mutation (SNP) | VAF 189/578 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RXFP2 | c.697A>C p.N233H | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RYR1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERGEF | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SERGEF | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 77/529 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SGIP1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SHISAL2B | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.057); called by muse, mutect2
- SHROOM1 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 179/572 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SOX6 | c.1531C>T p.Q511* (on ENST00000528429 / NM_001145819.2; = p.Q484* on NM_017508.3) | Nonsense Mutation (SNP) | VAF 162/534 reads (30%) | called by muse, mutect2, varscan2
- SRPK2 | c.647A>G p.K216R | Missense Mutation (SNP) | VAF 21/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- STK39 | c.1375A>G p.R459G | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SZT2 | c.8143G>A p.D2715N (on ENST00000634258 / NM_001365999.1; = p.D2658N on NM_015284.4) | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TACC1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 149/677 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TAS2R41 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 102/552 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TAS2R50 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 20/712 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.017); called by muse, mutect2
- TEX36 | c.373A>C p.N125H | Missense Mutation (SNP) | VAF 38/354 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); called by muse, mutect2
- TEX36 | c.372T>A p.N124K | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TLK1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- TMEM231 | c.923G>A p.G308E (on ENST00000258173 / NM_001077418.3; = p.G337E on NM_001077416.2) | Missense Mutation (SNP) | VAF 122/455 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNS4 | c.1657A>G p.T553A | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- TRAV19 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 102/349 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TTC22 | c.1147T>C p.F383L | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP17L17 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 32/1990 reads (2%) | SIFT tolerated (0.35); PolyPhen benign (0.15); called by muse, mutect2
- ZNF148 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 120/441 reads (27%) | called by muse, mutect2, varscan2
- ZNF570 | c.81A>T p.E27D | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF717 | c.2170T>C p.F724L | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, varscan2
- ADGRD1 | c.1371C>T p.F457= | Silent (SNP) | VAF 118/442 reads (27%) | catalogued as rs760071012, COSV55445612; called by muse, mutect2, varscan2
- ADRA2B | c.198C>T p.I66= | Silent (SNP) | VAF 136/520 reads (26%) | called by muse, mutect2, varscan2
- AGPAT3 | c.63C>T p.F21= | Silent (SNP) | VAF 112/432 reads (26%) | catalogued as rs756120469; called by muse, mutect2, varscan2
- ARHGAP15 | c.378C>T p.S126= | Silent (SNP) | VAF 53/277 reads (19%) | catalogued as COSV54496861; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 101/404 reads (25%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BRINP2 | c.606C>T p.F202= | Silent (SNP) | VAF 22/560 reads (4%) | called by muse, mutect2
- BRINP2 | c.1494C>G p.S498= | Silent (SNP) | VAF 114/498 reads (23%) | called by muse, mutect2, varscan2
- BRMS1 | c.492C>T p.I164= | Silent (SNP) | VAF 100/431 reads (23%) | called by muse, mutect2, varscan2
- BTAF1 | c.1866C>T p.I622= | Silent (SNP) | VAF 38/240 reads (16%) | catalogued as rs376665459; called by muse, mutect2, varscan2
- CABIN1 | c.775C>T p.L259= | Silent (SNP) | VAF 90/395 reads (23%) | called by muse, mutect2, varscan2
- CACNA1E | c.6513C>T p.S2171= (on ENST00000367573 / NM_001205293.3; = p.S2128= on NM_000721.4) | Silent (SNP) | VAF 25/628 reads (4%) | called by muse, mutect2
- CACNA2D3 | c.2418C>T p.L806= | Silent (SNP) | VAF 155/511 reads (30%) | catalogued as COSV99878157; called by muse, mutect2, varscan2
- CAPN7 | c.2331A>C p.I777= | Silent (SNP) | VAF 62/303 reads (20%) | called by muse, mutect2, varscan2
- CDHR2 | c.2172G>A p.T724= | Silent (SNP) | VAF 69/405 reads (17%) | catalogued as rs576263638, COSV56136996; called by muse, mutect2, varscan2
- CFAP47 | c.2880G>A p.R960= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- COG7 | c.1687C>T p.L563= | Silent (SNP) | VAF 106/259 reads (41%) | called by muse, mutect2, varscan2
- CYP3A43 | c.1467T>A p.I489= (on ENST00000354829 / NM_057095.3; = p.I490= on NM_022820.5) | Silent (SNP) | VAF 60/261 reads (23%) | called by muse, mutect2, varscan2
- DROSHA | c.396C>T p.V132= | Silent (SNP) | VAF 118/465 reads (25%) | catalogued as COSV60772656; called by muse, mutect2, varscan2
- EBF3 | c.1689C>T p.F563= (on ENST00000355311 / NM_001375392.1; = p.F518= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/470 reads (11%) | catalogued as rs373301366; called by muse, mutect2, varscan2
- EBF3 | c.951G>A p.P317= (on ENST00000355311 / NM_001375392.1; = p.P308= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 138/365 reads (38%) | catalogued as rs1283417086; called by muse, mutect2, varscan2
- ELOVL5 | c.330C>T p.I110= | Silent (SNP) | VAF 59/332 reads (18%) | called by muse, mutect2, varscan2
- EPHB6 | c.1339T>C p.L447= | Silent (SNP) | VAF 154/779 reads (20%) | called by muse, mutect2, varscan2
- FAM71F1 | c.684G>A p.S228= | Silent (SNP) | VAF 79/189 reads (42%) | catalogued as rs1206883314, COSV100170878; called by muse, mutect2, varscan2
- FCN2 | c.147C>T p.L49= | Silent (SNP) | VAF 109/331 reads (33%) | called by muse, mutect2, varscan2
- GPR148 | c.120G>A p.G40= | Silent (SNP) | VAF 143/492 reads (29%) | catalogued as COSV59309009; called by muse, mutect2, varscan2
- GRID2 | c.597G>A p.K199= | Silent (SNP) | VAF 127/461 reads (28%) | catalogued as rs771158401; called by muse, mutect2, varscan2
- HAVCR1 | c.160C>T p.L54= | Silent (SNP) | VAF 140/504 reads (28%) | called by muse, mutect2, varscan2
- HIRA | c.378C>T p.I126= | Silent (SNP) | VAF 82/376 reads (22%) | catalogued as rs763569767; called by muse, mutect2, varscan2
- IFIT5 | c.375G>A p.K125= | Silent (SNP) | VAF 31/320 reads (10%) | called by muse, mutect2, varscan2
- IL7R | c.894C>T p.F298= | Silent (SNP) | VAF 53/264 reads (20%) | catalogued as COSV57405582; called by muse, mutect2, varscan2
- ITGAD | c.2217C>T p.P739= | Silent (SNP) | VAF 99/239 reads (41%) | called by muse, mutect2, varscan2
- ITPR1 | c.1623C>T p.L541= (on ENST00000354582; = p.L526= on NM_002222.7) | Silent (SNP) | VAF 96/498 reads (19%) | catalogued as rs886058612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDR | c.3600C>T p.S1200= | Silent (SNP) | VAF 19/591 reads (3%) | called by muse, mutect2
- KIF21B | c.162C>T p.F54= | Silent (SNP) | VAF 83/484 reads (17%) | catalogued as rs139306112, COSV59752030; called by muse, mutect2, varscan2
- LRIT1 | c.1206G>A p.K402= | Silent (SNP) | VAF 34/416 reads (8%) | catalogued as COSV64513329; called by muse, mutect2
- MAP3K10 | c.501C>T p.P167= | Silent (SNP) | VAF 188/572 reads (33%) | called by muse, mutect2, varscan2
- ME1 | c.186C>T p.F62= | Silent (SNP) | VAF 100/328 reads (30%) | catalogued as rs748274488, COSV63838212; called by muse, varscan2
- MGAM | c.4602G>A p.L1534= | Silent (SNP) | VAF 20/604 reads (3%) | called by muse, mutect2
- MGRN1 | c.1212C>T p.A404= | Silent (SNP) | VAF 214/896 reads (24%) | called by muse, mutect2, varscan2
- MTHFR | c.792C>T p.S264= | Silent (SNP) | VAF 66/224 reads (29%) | catalogued as rs1309422719, COSV64876956; called by muse, mutect2, varscan2
- MYO7A | c.2676G>A p.E892= | Silent (SNP) | VAF 163/429 reads (38%) | catalogued as COSV101289196; called by muse, mutect2, varscan2
- MYO7B | c.1137G>A p.G379= | Silent (SNP) | VAF 98/341 reads (29%) | called by muse, mutect2, varscan2
- MYRIP | c.2016C>T p.V672= | Silent (SNP) | VAF 118/444 reads (27%) | called by muse, mutect2, varscan2
- NCAPD2 | c.1890C>T p.F630= | Silent (SNP) | VAF 121/410 reads (30%) | called by muse, mutect2, varscan2
- NCOR1 | c.672C>T p.S224= | Silent (SNP) | VAF 77/406 reads (19%) | catalogued as rs72835314; called by muse, mutect2, varscan2
- NLRC4 | c.597C>T p.F199= | Silent (SNP) | VAF 137/471 reads (29%) | catalogued as rs542279142, COSV61591549; called by muse, mutect2, varscan2
- NOS1 | c.2088C>T p.F696= | Silent (SNP) | VAF 158/461 reads (34%) | catalogued as rs1259344129, COSV57621472; called by muse, mutect2, varscan2
- NRK | c.1113G>A p.L371= | Silent (SNP) | VAF 89/239 reads (37%) | called by muse, mutect2, varscan2
- NSF | c.1785C>T p.S595= | Silent (SNP) | VAF 122/460 reads (27%) | called by muse, mutect2, varscan2
- OR10G8 | c.792G>A p.R264= | Silent (SNP) | VAF 47/364 reads (13%) | catalogued as rs760514680, COSV101461838, COSV70909599; called by muse, mutect2, varscan2
- OR2AG2 | c.498C>T p.L166= | Silent (SNP) | VAF 116/423 reads (27%) | catalogued as COSV58455172; called by muse, mutect2, varscan2
- OR4K2 | c.897G>A p.R299= | Silent (SNP) | VAF 11/246 reads (4%) | catalogued as rs1291478184, COSV53848607, COSV53849458; called by muse, mutect2
- OR5F1 | c.579C>T p.I193= | Silent (SNP) | VAF 15/385 reads (4%) | catalogued as COSV53545369, COSV53547790; called by muse, mutect2
- PCDHA3 | c.1284G>A p.R428= | Silent (SNP) | VAF 189/604 reads (31%) | catalogued as rs782571599, COSV63538565; called by muse, mutect2, varscan2
- PCDHA3 | c.1668G>A p.L556= | Silent (SNP) | VAF 213/719 reads (30%) | catalogued as rs1554122421; called by muse, mutect2, varscan2
- PCDHA5 | c.2199G>A p.R733= | Silent (SNP) | VAF 102/464 reads (22%) | called by muse, mutect2, varscan2
- PDE6C | c.114G>A p.K38= | Silent (SNP) | VAF 118/290 reads (41%) | called by muse, varscan2
- PGC | c.1101C>T p.F367= | Silent (SNP) | VAF 44/768 reads (6%) | catalogued as COSV100026419; called by muse, mutect2
- PGM5 | c.1026C>T p.T342= | Silent (SNP) | VAF 88/368 reads (24%) | catalogued as rs1362011852, COSV101123340; called by muse, mutect2, varscan2
- PHC3 | c.2886A>G p.A962= (on ENST00000494943 / NM_001308116.2; = p.A974= on NM_024947.4) | Silent (SNP) | VAF 141/503 reads (28%) | called by muse, mutect2, varscan2
- PSD | c.69C>T p.R23= | Silent (SNP) | VAF 43/400 reads (11%) | called by muse, mutect2, varscan2
- PUF60 | c.21T>C p.A7= | Silent (SNP) | VAF 76/450 reads (17%) | called by muse, varscan2
- RBP2 | c.393C>T p.F131= | Silent (SNP) | VAF 18/464 reads (4%) | called by muse, mutect2
- RETSAT | c.1668C>T p.S556= | Silent (SNP) | VAF 73/562 reads (13%) | called by muse, mutect2, varscan2
- ROBO2 | c.1668C>T p.I556= | Silent (SNP) | VAF 84/300 reads (28%) | called by muse, mutect2, varscan2
- SEC14L4 | c.1197G>A p.A399= | Silent (SNP) | VAF 81/345 reads (23%) | catalogued as rs769327241; called by muse, mutect2, varscan2
- SGSM1 | c.3411C>T p.L1137= (on ENST00000400359 / NM_001039948.4; = p.L1076= on NM_133454.3) | Silent (SNP) | VAF 90/397 reads (23%) | catalogued as rs751012612, COSV68509377; called by muse, mutect2, varscan2
- SLC22A25 | c.564C>T p.T188= | Silent (SNP) | VAF 20/465 reads (4%) | called by muse, mutect2
- SLC4A11 | c.168C>T p.F56= | Silent (SNP) | VAF 140/326 reads (43%) | catalogued as rs577502313, COSV66260244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SP140L | c.1080C>T p.G360= | Silent (SNP) | VAF 132/449 reads (29%) | catalogued as rs367991609; called by muse, mutect2, varscan2
- SPEF2 | c.93C>T p.G31= | Silent (SNP) | VAF 83/386 reads (22%) | called by muse, mutect2, varscan2
- SPRY4 | c.708C>T p.S236= (on ENST00000434127 / NM_001127496.3; = p.S259= on NM_030964.4) | Silent (SNP) | VAF 207/602 reads (34%) | catalogued as rs372429914; called by muse, mutect2, varscan2
- STARD7 | c.165C>G p.R55= | Silent (SNP) | VAF 136/564 reads (24%) | called by muse, mutect2, varscan2
- THSD7B | c.3532C>T p.L1178= (on ENST00000272643; = p.L1176= on NM_001316349.2) | Silent (SNP) | VAF 118/412 reads (29%) | catalogued as COSV99748274; called by muse, mutect2, varscan2
- THSD7B | c.4785G>A p.Q1595= (on ENST00000272643; = p.Q1593= on NM_001316349.2) | Silent (SNP) | VAF 110/429 reads (26%) | called by muse, mutect2, varscan2
- TMEM205 | c.550C>T p.L184= | Silent (SNP) | VAF 111/372 reads (30%) | called by muse, mutect2, varscan2
- TMEM63C | c.78G>A p.R26= | Silent (SNP) | VAF 178/644 reads (28%) | catalogued as COSV53603555; called by muse, mutect2, varscan2
- TMX4 | c.225G>A p.E75= | Silent (SNP) | VAF 11/281 reads (4%) | catalogued as rs1206560215; called by muse, mutect2
- TNFRSF8 | c.1323G>A p.R441= | Silent (SNP) | VAF 114/380 reads (30%) | called by muse, mutect2, varscan2
- TPO | c.378C>T p.I126= | Silent (SNP) | VAF 99/359 reads (28%) | catalogued as COSV100221120; called by muse, mutect2, varscan2
- TRGV9 | c.213C>T p.S71= | Silent (SNP) | VAF 84/271 reads (31%) | called by muse, mutect2, varscan2
- TRIM71 | c.2565C>T p.I855= | Silent (SNP) | VAF 31/430 reads (7%) | catalogued as rs146296287; called by muse, mutect2
- UTP25 | c.661C>T p.L221= | Silent (SNP) | VAF 81/298 reads (27%) | called by muse, mutect2, varscan2
- UTRN | c.5709C>T p.F1903= | Silent (SNP) | VAF 84/207 reads (41%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.240G>A p.T80= (on ENST00000268616; = p.T217= on NM_015144.3) | Silent (SNP) | VAF 119/287 reads (41%) | catalogued as rs777346493, COSV51887136; called by muse, mutect2, varscan2
- ZFAT | c.3393C>T p.I1131= | Silent (SNP) | VAF 88/478 reads (18%) | called by muse, mutect2
- ZNF318 | c.4095C>T p.A1365= | Silent (SNP) | VAF 111/538 reads (21%) | called by muse, mutect2, varscan2
- ZNF479 | c.1305A>G p.R435= | Silent (SNP) | VAF 150/560 reads (27%) | called by muse, varscan2
- ZNF792 | c.1380C>T p.S460= | Silent (SNP) | VAF 162/490 reads (33%) | called by muse, mutect2, varscan2
- AL583785.1 | n.417G>A | RNA (SNP) | VAF 18/397 reads (5%) | catalogued as rs1156586540; called by muse, mutect2
- CACNA1A | c.5547-1216C>T | Intron (SNP) | VAF 85/277 reads (31%) | catalogued as rs1057518533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD300LD | chr17:74592368 G>A | 5'Flank (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- EIF4A2 | c.-1C>T | 5'UTR (SNP) | VAF 66/402 reads (16%) | catalogued as rs774354910, COSV60623415; called by muse, mutect2, varscan2
- EREG | c.*1103G>A | 3'UTR (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+27955C>T | Intron (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-1225G>A | Intron (SNP) | VAF 259/1099 reads (24%) | called by muse, mutect2, varscan2
- RBFOX1 | c.318+235C>T | Intron (SNP) | VAF 35/624 reads (6%) | called by muse, mutect2
- SLIT1 | c.1086-789G>A | Intron (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- SYNE1 | c.5100+25G>A | Intron (SNP) | VAF 83/284 reads (29%) | catalogued as rs762932764, COSV99564342; called by muse, mutect2, varscan2
